Gene-level copy-number profile of tumor specimen TCGA-HM-A6W2-06A from TCGA case TCGA-HM-A6W2, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 35.0 years (12,775 days).
Specimen TCGA-HM-A6W2-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.ec15fb74-a4dc-44a2-a11b-990627da774a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HM-A6W2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 436 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f8a69c87-bc26-49b5-b46a-aae8b77aec0c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 559; copy number 1: 8,600; copy number 2: 44,424; copy number 3: 4,818; copy number 4: 1,078; copy number 5: 502; copy number 6: 10; copy number 7: 1; copy number 8: 158; copy number 9: 8; copy number 10: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HM-A6W2-06A-22D-A33N-01): tumor purity 0.89, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:158,419,955–158,682,879, 4 genes (within-gene range 0–2): HNRNPDLP2, RN7SL393P, PKP4, RPL7AP22.
- chr3:81,762,706–82,463,675, 4 genes (within-gene range 0–1): AC017015.2, AC129807.1, LINC02008, RPL7AP23.
- chr4:19,455,418–19,938,448, 1 gene (within-gene range 0–3): AC024230.1.
- chr6:151,404,762–151,470,101, 3 genes: RMND1, HSPA8P15, ARMT1.
- chr7:105,013,425–105,115,019, 2 genes (within-gene range 0–2): KMT2E-AS1, KMT2E.
- chr7:110,590,082–110,592,204, 1 gene: AC073326.2.
- chr7:110,724,159–110,725,825, 1 gene: AC073326.1.
- chr13:98,329,655–98,333,236, 1 gene: AL161896.1.
- chr13:113,491,021–113,641,473, 4 genes (within-gene range 0–1): TMCO3, AL442125.2, AL442125.1, TFDP1.
- chr14:33,677,360–33,682,886, 1 gene: AL161851.2.
- chr16:89,267,630–89,490,561, 1 gene (within-gene range 0–2): ANKRD11.
- chr16:89,420,075–89,557,766, 6 genes (within-gene range 0–2): AC092120.1, AC092120.3, RNU6-430P, AC092120.2, SPG7, AC092123.1.
- chr22:28,794,555–29,057,488, 5 genes (within-gene range 0–2): XBP1, Z93930.2, Z93930.3, Z93930.1, ZNRF3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 708 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:229,812,917–237,833,988, 164 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr1:246,682,108–246,839,611, 9 genes, copy number 5: AL591848.2, AL591848.1, SCCPDH, RPL35AP6, KIF28P, AL591848.3, LINC01341, AC113174.1, AC113174.2.
- chr2:38,814–17,817,798, 267 genes, copy number 5 (broad region; genes not listed).
- chr2:18,040,606–18,040,733, 1 gene, copy number 5: AC079802.1.
- chr2:88,811,186–88,861,563, 1 gene, copy number 8 (within-gene range 3–8): AC244205.1.
- chr2:88,857,161–88,979,081, 14 genes, copy number 8: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7.
- chr3:168,858,659–169,038,416, 5 genes, copy number 10: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr3:172,039,578–172,523,475, 8 genes, copy number 9 (within-gene range 3–9): FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1.
- chr9:60,914,407–68,330,626, 169 genes, copy number 5 (broad region; genes not listed).
- chr9:68,353,614–68,406,500, 2 genes, copy number 5: PGM5-AS1, AL161457.2.
- chr11:101,029,624–101,129,813, 1 gene, copy number 7 (within-gene range 1–7): PGR.
- chr15:24,341,729–24,343,464, 1 gene, copy number 5: AC087463.3.
- chr19:27,638,483–30,713,538, 66 genes, copy number 5–10 (within-gene range 1–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,111. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
